TARGET case TARGET-00-NAAENH — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026).
https://portal.gdc.cancer.gov/cases/78246c3a-6485-4791-9a7b-35e5a9a8e91a

Biospecimens (1 sample)
- Sample TARGET-00-NAAENH-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue.
